CCDI case PBBZAH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/d5b58ee9-3dd8-4526-a965-41d1201c07b0

Demographics
Sex at birth: male; Race: black or african american; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Age at diagnosis: 13.3 years (4,842 days).

Biospecimens (3 samples)
- Sample 0DLHO8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLHOI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLHOZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
